Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAFG, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAFG-05A (Additional - New Primary).

ICD O-3
Seminoma NOS 9061/3
Site: @ Testis NOS C62.9
JW 3/13/14

Concerning

Summary pathology report

Left orchidectomy; seminoma; diameter 3 cm; tumor confined to testis in available slides; no angio-invasion; invasion in rete testis present.

is bilateral to

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

2nd Primary

Criteria	hw 1/18/14	Yes	No

Source: NCI Genomic Data Commons file aaf20c00-80ad-4d36-889f-99e809c6168a (TCGA-2G-AAFG.2884217A-1112-4999-9D29-C48E93DB72B3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).